Surgical pathology report (de-identified scan), TCGA case TCGA-2Y-A9HB, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-2Y-A9HB-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

ICD-O-3
Carcinoma, hepatocellular NOS
8176/3
Site: Liver C22.0
QW 4/28/14

Final Diagnosis

- A. GALLBLADDER AND CONTENTS, CHOLECYSTECTOMY:
Chronic cholecystitis with cholesterosis.
There is no evidence of dysplasia or carcinoma.
- B. LIVER, SEGMENT 4B, "HEPATOMA", SEGMENTAL RESECTION:
Hepatocellular carcinoma, well to moderately differentiated, arising in a background of cirrhosis. See Key Pathological Findings. See comment.

I, _____ the attending pathologist, personally reviewed all slides and / or materials and rendered the final diagnosis. Electronically signed out by _____

Comment

The tumor is immunohistochemically positive for HepPar-1 and Glypican 3, and negative for AFP, cytokeratin 7 and cytokeratin 20. The immunostains were performed with appropriate controls. These results support the above diagnosis.

Key Pathological Findings

Specimen type: Hepatic segmental resection.
Tumor size: 2.6 cm in largest diameter.
Histologic type: Hepatocellular carcinoma.
Histologic grade: Well to moderately differentiated.
Tumor necrosis: No necrosis.
Perineural invasion: Not identified.
Venous (large vessel) invasion: Not identified.
Angiolymphatic invasion: Present.
Parenchymal margin: Negative of malignancy.
Additional Pathologic Findings: Cirrhosis, moderately active.
Lymph nodes: No Lymph nodes identified.

-

Specimen(s) Received

- A GALLBLADDER AND CONTENTS
B RESECTION SEGMENT 4B LIVER HEPATOMA GROSS MARGINS

Clinical History

Hepatocellular carcinoma segment 5.

[page 2 of 2]
Preoperative Diagnosis

None provided.

Intraoperative Consultation

GROSS EXAMINATION:

- B. RESECTION SEGMENT 4B LIVER HEPATOMA, GROSS MARGINS:
Tumor, 2 cm from margin.

Comment: This gross section diagnosis/result was communicated to and acknowledged by
in OR

I, _____ have performed the intraoperative consultation and issued the above
diagnosis.

Gross Description

A. The specimen is received fresh, labeled "gallbladder and contents," and consists of an intact gallbladder 29.9 g, 7 x 2.4 x 2.4 cm. The serosa is pale green-gray, smooth and glistening. The resection margin is roughened with cauterization. The cystic duct is patent (3 mm diameter). The lumen contains abundant dark green viscous bile. No calculus is seen. The mucosa is bile-stained with yellow streaks. The cut surfaces exhibit soft, congested tissue with a wall thickness of 1-2 mm. No lesion is grossly seen. Representative sections, including the cystic duct margin are submitted in A1-A2:

- A1: Cystic duct margin, tangential.
A2: Representative of neck, body, and fundus mucosa.

The specimen is not submitted for Tissue Procurement Laboratory.

B. The specimen is received fresh for gross consult, labeled "resection segment 4B liver hepatoma," and consists of a red-tan, unoriented, firm, partial hepatectomy specimen, 101.7 g, 6.7 x 5.9 x 5 cm. The capsule is intact and bosselated. The margin of resection is inked blue. The cut surfaces exhibit a light green-tan, circumscribed, firm, lobulated tumor mass, 2.6 cm diameter. The mass approximates the capsule separated by a thin membrane, and is 1.9 cm from nearest resection margin. The mass abuts vasculature; however, appears to be unaffected. Necrosis is minimal, and no cyst or hemorrhage is seen. The remaining parenchyma is tan-gray, coarsely lobulated and smooth. Representative sections are submitted in B1-B5 as labeled:

- B1: Mass to nearest resection margin.
B2-B3: Mass with capsule and adjacent vasculature.
B4: Mass with capsule and potential satellite lesion (7 mm).
B5: Normal parenchyma.

The specimen is submitted for Tissue Procurement Laboratory, as reflected in cassette B2.

Source: NCI Genomic Data Commons file 508ba000-9fce-48a0-ab6d-e6715f77bac4 (TCGA-2Y-A9HB.B5784B06-665F-4DA3-A3EF-CF98A84B2FB7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).